Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4642, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4642-01B (Primary Tumor).

Pathology Report
DIAGNOSIS

TCGA-CJ-4642

(A) RIGHT KIDNEY AND ADRENAL GLAND:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN NUCLEAR GRADE 2.

TUMOR CONFINED TO KIDNEY.

TUMOR MEASURES 8.0 CM IN MAXIMUM DIMENSION.

Vascular, ureter and soft tissue margins of resection free of tumor.

Adrenal gland, free of tumor.

GROSS DESCRIPTION

(A) RIGHT KIDNEY AND ADRENAL GLAND - A radical nephrectomy specimen (19.0 x 12.5 x 9.0 cm) including the right kidney (15.5 x 7.7 x 7.5 cm), a segment of renal artery, renal vein and ureter (2.0 cm in length and 0.2 cm in average diameter) and the adrenal gland (3.5 x 1.0 x 3.0 cm).

There is a 8.0 x 7.0 x 7.0 cm well circumscribed lobulated tumor in the mid pole of the kidney extending to the lower pole. The tumor is variegated pale yellow-tan to red-tan cut surface with areas of hemorrhage. Focal cystic areas are present within the tumor. The tumor is confined to the kidney and does not invade into the perinephric adipose tissue, renal sinus, or renal vein. The tumor does not extends to Gerota's fascia.

The adjacent kidney parenchyma is unremarkable. The pelvicalyceal system is smooth and devoid of any lesion. No lymph nodes are identified in the hilum of the kidney. Serial cross sections of the right adrenal gland show unremarkable cortex and medulla.

Portion of the tumor submitted for electron microscopy and Tumor Bank.

INK CODE: Blue- soft tissue margin

SECTION CODE: A1, ureter, renal artery and renal vein margin; A2, adrenal gland; A3-A7, tumor with perinephric fat and closest soft tissue margin (cassette A4 with inked margin); A8-A9, tumor with renal sinus; A10-A12, representative sections of tumor; A13, tumor with perinephric fat and inked margin; A14, A15, tumor with adjacent renal parenchyma; A16-A17, representative sections of non-neoplastic kidney.

CLINICAL HISTORY

Right renal mass.

Source: NCI Genomic Data Commons file 719eedad-282f-40bd-84c3-66bf95df98de (TCGA-CJ-4642.EA39C609-1EA1-48DD-8519-4ABBB965DC8D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).